Somatic mutation profile of tumor specimen TCGA-DB-A4XG-01A (aliquot TCGA-DB-A4XG-01A-11D-A27K-08) from TCGA case TCGA-DB-A4XG, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Frontal lobe; Tumor grade: G3; Age at diagnosis: 34.4 years (12,550 days).
Specimen TCGA-DB-A4XG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a21b3645-df5a-4bbd-a09a-5b1096521c5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A4XG-10A (Blood Derived Normal), aliquot TCGA-DB-A4XG-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/972b040c-3d5b-4fe2-aba4-4aa9ffe44e44

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Del 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 52/108 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6852_6855del p.Y2285Tfs*5 (on ENST00000358273 / NM_001042492.3; = p.Y2264Tfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 64/84 reads (76%) | catalogued as rs1555535032; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NOTCH1 | c.1367G>A p.C456Y | Missense Mutation (SNP) | VAF 72/113 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs864622058, CM159416, COSV53046494, COSV53053704; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C3 | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs1220580146, COSV55573887; called by muse, mutect2, varscan2
- CDH16 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs761222104, COSV55336428; called by muse, mutect2, varscan2
- COL4A5 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 75/81 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM052207, COSV60362754; called by muse, mutect2, varscan2
- EML4 | c.2279G>T p.R760L | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.835); catalogued as COSV59298936, COSV59301226; called by muse, mutect2, varscan2
- FGD5 | c.2702T>C p.L901P | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as COSV53244030; called by muse, mutect2, varscan2
- HERC1 | c.7775C>T p.A2592V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs749237440, COSV71248042; called by muse, mutect2, varscan2
- MAP3K15 | c.3597_3600del p.R1199Sfs*10 | Frame Shift Del (DEL) | VAF 29/80 reads (36%) | catalogued as rs747607452; called by mutect2, pindel, varscan2
- MATN2 | c.2754T>G p.C918W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54712191; called by muse, mutect2, varscan2
- MUC5B | c.12296C>T p.T4099M | Missense Mutation (SNP) | VAF 116/249 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); catalogued as rs367864174; called by muse, varscan2
- NIPBL | c.5375C>A p.A1792D | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56952657, COSV56964461; called by muse, mutect2, varscan2
- POF1B | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs769700681, COSV53134884; called by muse, mutect2, varscan2
- STX11 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV100845464; called by muse, mutect2
- SYNRG | c.2727_2728del p.P910Ifs*27 | Frame Shift Del (DEL) | VAF 19/118 reads (16%) | called by pindel, varscan2
- TNS1 | c.1946_1958delinsT p.S649_Q653delinsL | In Frame Del (DEL) | VAF 5/25 reads (20%) | called by pindel, varscan2*
- ZCWPW1 | c.395_397del p.S132del | In Frame Del (DEL) | VAF 18/92 reads (20%) | called by pindel, varscan2
- ANKIB1 | c.1338C>T p.L446= | Silent (SNP) | VAF 161/342 reads (47%) | catalogued as COSV56061325, COSV56061993; called by muse, mutect2, varscan2
- CCN4 | c.276C>T p.I92= | Silent (SNP) | VAF 53/137 reads (39%) | catalogued as COSV51532402; called by muse, mutect2, varscan2
- CD209 | c.834C>T p.H278= | Silent (SNP) | VAF 54/125 reads (43%) | catalogued as rs61742035, COSV52654363; called by muse, mutect2, varscan2
- CDK5RAP2 | c.39T>C p.P13= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs755003940, COSV62574665; called by muse, mutect2, varscan2
- LRP2 | c.2748G>A p.P916= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as rs570664576, COSV55555831; called by muse, mutect2
- SIM1 | c.1018C>T p.L340= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV53492586; called by muse, mutect2, varscan2
